Gene-level copy-number profile of tumor specimen TCGA-X6-A7WC-01A from TCGA case TCGA-X6-A7WC, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 74.6 years (27,252 days).
Specimen TCGA-X6-A7WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.07fbe2a0-470a-4fdb-99e2-8ac308e39473.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A7WC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d32b175f-3594-412a-94eb-dcb42120b3c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,762; copy number 2: 20,165; copy number 3: 18,396; copy number 4: 11,194; copy number 5: 5,152; copy number 6: 1,252; copy number 7: 341; copy number 8: 297; copy number 9: 130; copy number 10: 207; copy number 11: 331; copy number 12: 309; copy number 13: 110; copy number 14: 69; copy number 17: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A7WC-01A-12D-A350-01): tumor purity 0.66, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,230 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,354,263–89,198,942, 614 genes, copy number 6–17 (broad region; genes not listed).
- chr3:1,008,135–1,404,217, 3 genes, copy number 5 (within-gene range 2–5): AC087430.1, RN7SL120P, CNTN6.
- chr3:1,905,651–5,256,761, 40 genes, copy number 5–6: RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1.
- chr3:10,324,023–10,708,007, 1 gene, copy number 5 (within-gene range 4–5): ATP2B2.
- chr3:10,566,255–19,702,795, 154 genes, copy number 5 (broad region; genes not listed).
- chr3:57,941,818–58,426,127, 12 genes, copy number 5 (within-gene range 3–5): PPIAP16, FLNB, FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2.
- chr3:84,638,405–90,261,708, 47 genes, copy number 6: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:134,597,801–135,260,467, 1 gene, copy number 5 (within-gene range 2–5): EPHB1.
- chr3:134,774,543–158,871,821, 404 genes, copy number 5 (broad region; genes not listed).
- chr4:65,216,616–65,670,495, 3 genes, copy number 5 (within-gene range 2–5): AC096754.1, LINC02835, EPHA5.
- chr4:65,998,846–66,431,521, 6 genes, copy number 5: AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3.
- chr4:134,932,889–150,051,290, 213 genes, copy number 5–6 (broad region; genes not listed).
- chr4:153,633,692–155,520,353, 48 genes, copy number 5: AC106865.2, AC106865.1, WDR45P1, TLR2, RNF175, AC020703.1, SFRP2, AC079298.3, DCHS2, AC079298.1, AC079298.2, AC110775.1, AC110753.1, PLRG1, RNU6-1285P, AC107385.1, FGB, FGA, FGG, AC107385.2, LRAT, NDUFB2P1, AC009567.1, AC009567.2, RBM46, RNU2-66P, RNU2-44P, AC097467.3, AC104407.1, NPY2R, AC097467.1, MAP9, YWHAEP4, AC097467.2, AC097467.4, AC097526.1, MTCYBP17, MTND6P17, MTND5P9, MTND4P8, MTND3P3, MTCO3P9, MTATP6P9, MTCO2P9, MTCO1P9, MTND2P33, MTND1P22, AC107208.1.
- chr4:158,769,026–159,777,828, 13 genes, copy number 6: FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233.
- chr5:58,198–45,895,970, 710 genes, copy number 6–11 (broad region; genes not listed).
- chr5:102,664,610–106,546,803, 25 genes, copy number 6–7: AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR, AC010406.1, PDZPH1P, LINC02115, NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1, RNA5SP189, AC027313.1, AC114940.1, AC114940.2.
- chr6:958,323–2,564,143, 22 genes, copy number 5: LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1.
- chr7:91,880,791–148,420,998, 1,155 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:30,729,131–31,033,715, 7 genes, copy number 5 (within-gene range 2–5): UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG.
- chr8:31,275,542–32,855,666, 11 genes, copy number 5 (within-gene range 2–5): AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3.
- chr8:33,370,824–34,874,633, 24 genes, copy number 5–6 (within-gene range 2–6): FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1.
- chr8:36,277,763–41,032,998, 105 genes, copy number 6 (broad region; genes not listed).
- chr11:71,929,018–71,997,597, 1 gene, copy number 6 (within-gene range 4–6): RNF121.
- chr11:71,998,613–85,627,922, 296 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:21,667,940–22,124,285, 42 genes, copy number 6 (within-gene range 4–6): OR4E1, AC243972.3, TRAV2, AC243972.1, TRAV3, TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1.
- chr14:24,595,723–34,462,774, 114 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr14:75,902,136–84,999,296, 124 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr14:88,465,778–88,555,007, 1 gene, copy number 7 (within-gene range 3–7): PTPN21.
- chr14:88,513,498–106,875,071, 733 genes, copy number 5–9 (broad region; genes not listed).
- chr15:101,289,784–101,525,202, 1 gene, copy number 5 (within-gene range 4–5): PCSK6.
- chr15:101,334,437–101,933,350, 23 genes, copy number 5: PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr17:7,402,975–7,592,789, 32 genes, copy number 11: TMEM256, NLGN2, AC113189.2, SPEM1, SPEM2, SPEM3, AC113189.12, TMEM102, AC113189.1, FGF11, AC113189.3, AC113189.4, CHRNB1, ZBTB4, SLC35G6, POLR2A, Y_RNA, TNFSF12, TNFSF12-TNFSF13, AC016876.3, TNFSF13, SENP3, SENP3-EIF4A1, EIF4A1, AC016876.2, SNORA48, SNORD10, SNORA67, CD68, AC016876.1, MPDU1, SOX15.
- chr17:7,717,354–28,445,563, 636 genes, copy number 5–13 (broad region; genes not listed).
- chr17:28,467,822–28,497,781, 2 genes, copy number 5: RPS7P1, SLC13A2.
- chr18:2,649,761–15,330,282, 320 genes, copy number 5 (broad region; genes not listed).
- chr19:3,172,346–15,934,867, 682 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:28,683,071–36,173,853, 252 genes, copy number 5–9 (broad region; genes not listed).
- chr19:56,477,250–58,605,223, 155 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–54,269,542, 1,192 genes, copy number 5 (broad region; genes not listed).
- chr20:60,755,001–61,083,750, 4 genes, copy number 5: AL117372.1, AL139348.1, AL121910.1, LINC01718.

Autosomal genes at a single copy (total copy number 1): 706. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
